Somatic mutation profile of tumor specimen C3N-00303-01 (aliquot CPT0008800006_1) from CPTAC case C3N-00303, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 66.0 years (24,091 days).
Specimen C3N-00303-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 03a6b3f6-de5c-46ab-8ce4-0b606c94dba4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00303-31 (Blood Derived Normal), aliquot CPT0008850002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a23ca3f8-bded-42de-a9cc-f4fbea81afb4

The open-access MAF lists 49 somatic variants for this specimen: 32 protein-altering or splice-affecting, 12 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 12, Intron 3, Nonsense Mutation 3, Splice Region 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.2339G>A p.R780K | Missense Mutation (SNP) | VAF 22/318 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705570, COSV66707409; called by muse, mutect2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 37/704 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ATP13A5 | c.1952C>T p.T651M | Missense Mutation (SNP) | VAF 30/452 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750724708, COSV60874539; called by muse, mutect2
- BEND4 | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 16/450 reads (4%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); catalogued as rs1048800530; called by muse, mutect2
- CSMD2 | c.10282G>A p.V3428M | Missense Mutation (SNP) | VAF 24/420 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as rs376804420; called by muse, mutect2
- DNAH9 | c.5483C>T p.A1828V | Missense Mutation (SNP) | VAF 18/393 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1428706801; called by muse, mutect2
- EPPK1 | c.6458C>T p.T2153M | Missense Mutation (SNP) | VAF 34/500 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.349); catalogued as rs201994568, COSV73262096; called by muse, mutect2
- GALNT9 | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs782621002, COSV61100433; called by muse, mutect2
- HAS3 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 18/334 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1304022988; called by muse, mutect2
- KMT2D | c.273G>A p.W91* | Nonsense Mutation (SNP) | VAF 44/802 reads (5%) | catalogued as COSV99040311; called by muse, mutect2
- MARK2 | c.1780C>T p.R594* (on ENST00000402010 / NM_001039469.2; = p.R539* on NM_004954.5) | Nonsense Mutation (SNP) | VAF 26/1027 reads (3%) | catalogued as COSV59281123; called by muse, mutect2
- PCDHGA2 | c.2211C>G p.S737R | Missense Mutation (SNP) | VAF 68/1476 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as COSV54006316; called by muse, mutect2
- PDE1B | c.1445G>A p.R482H | Missense Mutation (SNP) | VAF 31/600 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs202001120, COSV99226397; called by muse, mutect2
- PDZD2 | c.2614G>A p.D872N | Missense Mutation (SNP) | VAF 22/366 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs575891004, COSV56876078; called by muse, mutect2
- PGAP4 | c.143A>G p.H48R | Missense Mutation (SNP) | VAF 12/444 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.26); catalogued as rs962960183, COSV66387187; called by muse, mutect2
- RBMXL3 | c.1873G>A p.G625R | Missense Mutation (SNP) | VAF 38/700 reads (5%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs782496034, COSV57751588; called by muse, mutect2
- SHPRH | c.2386C>T p.R796W | Missense Mutation (SNP) | VAF 36/712 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs765062036, COSV51612664; called by muse, mutect2
- SRGAP1 | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 42/606 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs766358165, COSV100754519; called by muse, mutect2
- SYNPR | c.322C>T p.R108W | Missense Mutation (SNP) | VAF 17/245 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371885804; called by muse, mutect2
- TMEM44 | c.562G>A p.V188I | Missense Mutation (SNP) | VAF 32/482 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs199697463, COSV99861460; called by muse, mutect2
- VWC2L | c.542C>T p.T181M | Missense Mutation (SNP) | VAF 28/255 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs767822551, COSV56975317, COSV56978390; called by muse, mutect2, varscan2
- ADAMTS18 | c.973G>T p.V325F | Missense Mutation (SNP) | VAF 19/534 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DNAJC7 | c.793A>T p.K265* | Nonsense Mutation (SNP) | VAF 26/364 reads (7%) | called by muse, mutect2
- FBLN1 | c.1868C>A p.P623Q | Missense Mutation (SNP) | VAF 50/1226 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.296); called by muse, mutect2
- FBXL2 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 38/474 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.367); called by muse, mutect2
- FMC1-LUC7L2 | c.259+8C>A | Splice Region (SNP) | VAF 21/808 reads (3%) | called by muse, mutect2
- KRR1 | c.250A>C p.N84H | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2
- PIWIL1 | c.1023C>A p.S341R | Missense Mutation (SNP) | VAF 10/294 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PLEKHH1 | c.793C>A p.P265T | Missense Mutation (SNP) | VAF 31/311 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- SCN5A | c.4696C>A p.L1566I (on ENST00000333535 / NM_198056.3; = p.L1565I on NM_000335.5) | Missense Mutation (SNP) | VAF 21/491 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.061); called by muse, mutect2
- SEPTIN9 | c.971G>T p.S324I (on ENST00000427177 / NM_001113491.2; = p.S306I on NM_006640.4) | Missense Mutation (SNP) | VAF 28/980 reads (3%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.775); called by muse, mutect2
- TLL1 | c.434T>C p.V145A | Missense Mutation (SNP) | VAF 48/596 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.015); called by muse, mutect2
- CEP152 | c.1179C>T p.D393= | Silent (SNP) | VAF 25/408 reads (6%) | called by muse, mutect2
- FAT4 | c.5727G>A p.Q1909= | Silent (SNP) | VAF 16/236 reads (7%) | catalogued as COSV100628462; called by muse, mutect2
- FCRL1 | c.480C>T p.T160= | Silent (SNP) | VAF 31/956 reads (3%) | called by muse, mutect2
- GALNTL6 | c.1032C>A p.I344= | Silent (SNP) | VAF 20/226 reads (9%) | catalogued as COSV72492194; called by muse, mutect2
- MKRN3 | c.399G>A p.S133= | Silent (SNP) | VAF 16/478 reads (3%) | catalogued as rs905116093, COSV58810449; called by muse, mutect2
- MYCBP2 | c.13056G>A p.T4352= (on ENST00000357337; = p.T4390= on NM_015057.5) | Silent (SNP) | VAF 16/226 reads (7%) | catalogued as rs762181785, COSV62042237; called by muse, mutect2
- NPAS4 | c.1092C>T p.T364= | Silent (SNP) | VAF 13/414 reads (3%) | catalogued as rs1210861366, COSV60650653; called by muse, mutect2
- OR1S1 | c.459C>T p.F153= | Silent (SNP) | VAF 34/518 reads (7%) | catalogued as rs146740369; called by muse, mutect2
- PAX6 | c.1197T>A p.P399= | Silent (SNP) | VAF 21/706 reads (3%) | called by muse, mutect2
- PCDHA8 | c.2307C>T p.L769= | Silent (SNP) | VAF 25/567 reads (4%) | catalogued as COSV65333508; called by muse, mutect2
- PIGO | c.819A>C p.V273= | Silent (SNP) | VAF 23/283 reads (8%) | called by muse, mutect2
- ZBTB37 | c.1380G>A p.G460= | Silent (SNP) | VAF 74/973 reads (8%) | catalogued as rs1339695543; called by muse, mutect2
- ANO4 | c.-87C>T | 5'UTR (SNP) | VAF 33/378 reads (9%) | catalogued as rs1394681445, COSV54593142; called by muse, mutect2
- FAM27E5 | n.345G>T | RNA (SNP) | VAF 23/693 reads (3%) | called by muse, mutect2
- NLGN1 | c.494-7344C>T | Intron (SNP) | VAF 14/270 reads (5%) | catalogued as rs1365108591; called by muse, mutect2
- PPP4R3A | c.1266+51C>G | Intron (SNP) | VAF 7/94 reads (7%) | called by muse, mutect2
- TNS1 | c.-55+954C>T | Intron (SNP) | VAF 19/263 reads (7%) | catalogued as rs773362958; called by muse, mutect2
